Gene-level copy-number profile of tumor specimen TCGA-2H-A9GJ-01A from TCGA case TCGA-2H-A9GJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.0 years (21,180 days).
Specimen TCGA-2H-A9GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.2989ab1b-bbe4-432e-9c4d-b2ceb62d5063.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GJ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f4b3e9b-6b96-42bd-a6a6-22dde6d04c04

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 7; copy number 2: 5,913; copy number 3: 1,567; copy number 4: 36,102; copy number 5: 5,073; copy number 6: 10,118; copy number 7: 152; copy number 8: 359; copy number 9: 57; copy number 10: 49; copy number 11: 41; copy number 12: 42; copy number 14: 12; copy number 15: 9; copy number 16: 51; copy number 17: 91; copy number 18: 9; copy number 21: 19; copy number 22: 1; copy number 23: 12; copy number 24: 1; copy number 25: 75; copy number 28: 16; copy number 32: 18; copy number 51: 1; copy number 54: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GJ-01A-11D-A37B-01): tumor purity 0.83, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 514 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,837,819–152,196,699, 19 genes, copy number 9 (within-gene range 7–9): C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr6:29,993,209–30,327,382, 25 genes, copy number 10 (within-gene range 4–10): DDX39BP2, MCCD1P2, ZNRD1ASP, HLA-J, AL671277.2, ETF1P1, AL669914.3, AL669914.2, POLR1H, AL669914.4, PPP1R11, RNF39, TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10, TRIM15, TRIM26, PAIP1P1, HCG17, TRIM26BP, HLA-L, AL662795.2, HCG18.
- chr6:48,701,491–56,433,213, 128 genes, copy number 10–32 (broad region; genes not listed).
- chr7:69,186,821–69,430,923, 1 gene, copy number 9 (within-gene range 5–9): AC092100.1.
- chr7:69,330,698–69,597,493, 5 genes, copy number 9: MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr8:41,426,655–43,674,591, 75 genes, copy number 25 (broad region; genes not listed).
- chr8:49,740,216–49,820,944, 2 genes, copy number 16–18: PSAT1P1, AC113145.1.
- chr8:50,490,795–50,491,465, 1 gene, copy number 22: AC090539.2.
- chr8:74,548,543–74,866,939, 8 genes, copy number 18 (within-gene range 4–18): MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1.
- chr8:76,491,200–77,014,028, 9 genes, copy number 15: ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18.
- chr8:79,259,402–81,112,068, 44 genes, copy number 16–24 (within-gene range 4–24): AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2.
- chr8:121,954,640–122,127,184, 2 genes, copy number 14: AC037486.1, MRPS36P3.
- chr8:125,648,327–127,742,951, 31 genes, copy number 12–28 (within-gene range 4–28): AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:128,220,504–128,388,636, 2 genes, copy number 17: RN7SKP226, AC100822.1.
- chr8:135,625,185–137,092,183, 5 genes, copy number 16–17 (within-gene range 5–28): MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1.
- chr17:82,942,155–83,095,122, 3 genes, copy number 9: B3GNTL1, AC130371.1, METRNL.
- chr18:20,946,906–22,587,227, 41 genes, copy number 11: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18.
- chr18:23,453,287–23,956,222, 10 genes, copy number 14 (within-gene range 8–14): RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77.
- chr18:60,329,190–60,540,205, 1 gene, copy number 12 (within-gene range 4–12): AC091576.1.
- chr18:60,495,868–62,980,433, 33 genes, copy number 12: AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P.
- chr19:27,638,483–30,957,192, 69 genes, copy number 9–54 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
